Surgical pathology report (de-identified scan), TCGA case TCGA-06-6698, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-6698-01A (Primary Tumor).

[page 1 of 5]
Surgical Pathology Report

=====

CLINICAL HISTORY

developed progressive
three
months ago. On imaging there is a left frontal lobe-centered
enhancing mass
that extends into the corpus callosum. There are also several
enhancing
satellite lesions. MRS demonstrates increased levels of choline,
decreased
NAA, and no lipid or lactate spikes.

OPERATIVE DIAGNOSES

Left brain tumor

Operation/Specimen: A: Brain tumor, biopsy

PATHOLOGICAL DIAGNOSIS:

A. Brain, site not specified, excisional biopsies:

1. Glioblastoma
2. MIB-1 proliferation index: 20%.
- See Microscopy Description and Comment.

COMMENT

The sections contain portions of an astrocytic neoplastic
proliferation that
has nuclear anaplasia, mitotic activity, and sparse microvascular
cellular
proliferation with necrosis and microthrombosis. There are frequent
giant
cells, several of them multinucleated and bizarre. Some of the giant
cells
and smaller cells are immunoreactive with neuronal markers. The MIB-1
proliferation index is high at about 20% in the more active areas.
The findings are interpreted as those of a glioblastoma (WHO IV) with
probably
a neuronal component, which may portend a less grave prognosis.

[page 2 of 5]
PROCEDURES/ADDENDA

PCR for EGFR variant III mutation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

NEGATIVE - No evidence of EGFRvIII mutation is detected

Results-Comments

TEST DESCRIPTION: Testing performed on RNA extracted from paraffin block

H slide was examined and no microdissection was needed.

The epidermal growth factor receptor (EGFR) is an attractive molecular target

in glioblastoma because it is amplified, overexpressed, and/or mutated in up

to 40% to 50% of patients. Epidermal growth factor receptor variant III

(EGFRvIII) is an oncogenic, constitutively active mutant form of EGFR that is

commonly expressed in glioblastoma. Cell culture and in vivo models of glioblastoma have demonstrated EGFRvIII as defining prognostically distinct

subgroups of glioblastomas. Additionally, the presence of EGFRvIII has been

shown to sensitize tumors to EGFR tyrosine kinase inhibitors when the tumor

suppressor protein PTEN is intact. RNA is extracted from formalin fixed,

paraffin embedded tissue samples and reverse transcribed to cDNA. The cDNA is

then amplified using standard PCR technique for DNA templates. PCR products

are detected by gel electrophoresis. The limit of detection of this assay has

been determined to be approximately 5 mutant cells in 100 normal cells.

FDA Comment: The above data are not to be construed as the results from a

stand alone diagnostic test. This test was developed and its performance

characteristics determined by the [REDACTED] laboratory as required by CLIA [REDACTED] regulations. It has not been cleared or approved for

[page 3 of 5]
specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

Interpretation

NEGATIVE: No evidence of methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tumor paraffin block

H slide was examined and no microdissection was needed.

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter

have been shown to benefit from therapy with alkylating agents.

Assessment of

MGMT promoter methylation status involves bisulfite treatment of DNA followed

by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA

sequences. The analytic sensitivity of this assay was determined by serial

dilution of methylated positive control DNA into unmethylated DNA, and was

assessed to be 1% of methylated DNA in the background of unmethylated DNA.

Factors such as the presence of >50% non-neoplastic cells in the sample, or

extensive tissue necrosis, may preclude the detection of methylated MGMT

promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a

stand alone diagnostic test. This test was developed and its performance

characteristics determined by the laboratory as required by CLIA regulations. It has not been cleared or approved for

specific uses by the U.S. Food and Drug Administration (FDA). The FDA has

determined that such clearance or approval is not necessary. These results are

[page 4 of 5]
provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[REDACTED]

=====

INTRA-OPERATIVE CONSULTATION

A.

Brain tumor, biopsy: High histological grade glioma (C/W glioblastoma, other).

[REDACTED] Touch preparation smears performed at [REDACTED] and results reported to the Physician of Record. [REDACTED]

[REDACTED]

GROSS DESCRIPTION

A.

"Left brain tumor," received fresh, three fragments, 0.9 cm across in aggregate. Semi firm, pinkish-grey, glistening. In total, A1 and A2.

[REDACTED]

MICROSCOPIC DESCRIPTION

IMMUNOHISTOCHEMISTRY: There is prominent gliofibrillogenesis by the neoplastic cells, including occasionally by a giant cell. Less than a handful

of giant cells are reactive with NeuN or neurofilament (neuronal markers), and

a small population of small cells are NeuN-positive, possibly entrapped or

neoplastic neurons. The MAP is positive on many cells, probably glial and

neuronal. A great majority of tumor cells over expresses the p53 protein.

The MIB-1 proliferation index is about 20% in the more active areas.

ICD-9(s):

237.5 237.5

[REDACTED]

Histo Data

Part A: Brain tumor, biopsy

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
H/E x 1	1	[REDACTED]	
TPS H/E x 1	1	[REDACTED]	
CD34-DA x 1	2	[REDACTED]	
EGFR VIII-curls x 1	2	[REDACTED]	

[page 5 of 5]
mGFAP-DA x 1	2
H/E x 1	2
MGMT-curls x 1	2
MIB1-DA x 1	2
MAP2 c x 1	2
NeuN x 1	2
NF2F11 x 1	2
P53DO7 x 1	2
Retic x 1	2

*** End of Report ***

Source: NCI Genomic Data Commons file 308b470c-14ae-4114-8091-642cb143e8a6 (TCGA-06-6698.73D3D6FE-216D-48D6-AAA5-AFE8776964DD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).